Gene-level copy-number profile of tumor specimen TCGA-AP-A05A-01A from TCGA case TCGA-AP-A05A, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 81.9 years (29,914 days).
Specimen TCGA-AP-A05A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.23a28001-6e8e-4895-9a47-6aa88288a422.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AP-A05A-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6db6495d-fc9b-4efb-b631-6644cb210f63

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,252; copy number 2: 44,793; copy number 3: 7,680; copy number 4: 838; copy number 5: 226; copy number 6: 9; copy number 13: 2; copy number 21: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AP-A05A-01A-11D-A00X-01): tumor purity 0.95, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 252 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:28,384,409–29,052,230, 21 genes, copy number 5 (within-gene range 3–5): FLJ31356, FOSL2, AC104695.3, AC104695.2, AC104695.1, PLB1, SNRPGP7, AC074011.1, RNA5SP89, AC092164.1, PPP1CB, SPDYA, AC097724.1, TRMT61B, WDR43, SNORD92, SNORD53, Y_RNA, SNORD53B, TOGARAM2, Y_RNA.
- chr2:110,967,834–111,523,376, 12 genes, copy number 5 (within-gene range 3–5): RPL5P9, MIR4435-2HG, ACOXL-AS1, BCL2L11, AC108463.2, AC108463.1, AC108463.3, AC068491.1, AC068491.2, RPS14P4, MIR4435-2, PAFAH1B1P2.
- chr3:13,549,125–13,746,638, 2 genes, copy number 13 (within-gene range 3–13): FBLN2, LINC00620.
- chr3:196,027,183–196,211,437, 6 genes, copy number 5 (within-gene range 2–5): TFRC, AC024937.1, RNU7-18P, LINC00885, ZDHHC19, Y_RNA.
- chr6:10,886,831–11,811,248, 21 genes, copy number 5 (within-gene range 3–5): SYCP2L, ELOVL2, AL121955.1, ELOVL2-AS1, SMIM13, ERVFRD-1, AL136139.1, AL139807.1, NEDD9, AL022098.1, AL445430.2, AL445430.1, RNU1-64P, THAP12P5, TMEM170B, AL357518.1, Metazoa_SRP, AL022724.1, ADTRP, AL022724.3, AL022724.2.
- chr8:96,645,242–98,294,393, 25 genes, copy number 5 (within-gene range 3–5): CPQ, AP003117.2, AP003117.1, AP003115.1, TSPYL5, SNORD3H, AP002982.1, AP002982.2, MTDH, Y_RNA, LAPTM4B, AP003357.1, AP002906.1, SUMO2P18, RPS23P1, MATN2, RPL30, AP003352.1, SNORA72, RNU6-703P, ERICH5, RIDA, POP1, NIPAL2, RNU6-914P.
- chr8:98,391,401–98,463,050, 5 genes, copy number 5: AP003355.3, AP003355.1, KCNS2, AP003355.2, RNU6-748P.
- chr13:22,589,699–22,706,206, 3 genes, copy number 5: AL512484.1, FTH1P7, DDX39AP1.
- chr17:39,461,486–39,864,312, 15 genes, copy number 21 (within-gene range 1–21): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3.
- chr19:14,950,034–15,145,318, 9 genes, copy number 6 (within-gene range 2–6): SLC1A6, CCDC105, CASP14, OR1I1, SYDE1, ILVBL, AC003956.1, OR10B1P, RNU6-782P.
- chr20:45,252,239–45,708,817, 32 genes, copy number 5 (within-gene range 3–5): SLPI, MATN4, RBPJL, SDC4, AL021578.1, SYS1, SYS1-DBNDD2, TP53TG5, NDUFB4P10, DBNDD2, PIGT, MIR6812, AL031663.3, WFDC2, AL031663.2, RPL5P2, SPINT3, WFDC6, EPPIN-WFDC6, AL031663.1, HSPD1P21, EPPIN, WFDC8, RNA5SP485, CCNB1IP1P2, WFDC9, WFDC10A, RPS2P7, WFDC11, WFDC10B, WFDC13, MIR3617.
- chr20:61,953,469–62,427,539, 21 genes, copy number 5: TAF4, MIR1257, AL137077.1, MIR3195, AL137077.2, LSM14B, PSMA7, SS18L1, MTG2, HRH3, OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL.
- chr20:63,090,806–64,313,132, 80 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,249. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
